Gene-level copy-number profile of tumor specimen TCGA-36-2548-01A from TCGA case TCGA-36-2548, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.2 years (20,897 days).
Specimen TCGA-36-2548-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.86294b03-0b4e-432d-8fd1-7529422f0e7e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2548-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f642fba1-7a0f-4b21-86dd-4bf2cdb78f94

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 314; copy number 2: 23,252; copy number 3: 13,277; copy number 4: 18,554; copy number 5: 1,606; copy number 6: 1,049; copy number 7: 1,676; copy number 8: 34; copy number 10: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2548-01A-01D-1043-01): tumor purity 0.81, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,416 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,728,926–10,630,758, 34 genes, copy number 6 (within-gene range 4–6): CLSTN1, MZT1P1, AL357140.3, CTNNBIP1, AL357140.1, AL357140.4, LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P, KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P.
- chr1:10,639,241–10,654,333, 1 gene, copy number 6 (within-gene range 4–6): AL139423.1.
- chr1:24,496,254–24,717,596, 8 genes, copy number 8 (within-gene range 4–8): RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, AL445648.1.
- chr1:26,234,200–27,166,981, 41 genes, copy number 6: CEP85, AL355877.1, SH3BGRL3, UBXN11, CD52, CRYBG2, AL451139.1, ZNF683, LIN28A, DHDDS, AL513365.1, DHDDS-AS1, HMGN2, DPPA2P2, RPS6KA1, MIR1976, RN7SL679P, Y_RNA, RNU7-29P, AL627313.1, AL627082.2, AL627082.1, AL512408.1, ARID1A, PIGV, RN7SL165P, AL034380.2, ZDHHC18, SFN, GPN2, AL034380.1, GPATCH3, NUDC, NR0B2, KDF1, RPL12P13, AL356390.1, OSTCP2, TRNP1, TENT5B, SLC9A1.
- chr1:45,786,987–46,516,216, 20 genes, copy number 5 (within-gene range 3–5): MAST2, TMA16P2, PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1.
- chr1:159,800,511–160,647,295, 43 genes, copy number 7: FCRL6, SLAMF8, AL590560.2, SNHG28, AL590560.1, VSIG8, AL590560.3, CFAP45, MIR4259, AL590560.5, AL590560.4, TAGLN2, IGSF9, SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1.
- chr2:46,256,860–47,176,511, 27 genes, copy number 5 (within-gene range 3–5): RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1.
- chr2:120,319,007–121,088,726, 11 genes, copy number 5: AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1.
- chr3:10,816,201–11,557,665, 11 genes, copy number 5 (within-gene range 3–5): SLC6A11, AC027128.1, SLC6A1, SLC6A1-AS1, AC066580.1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1.
- chr3:44,874,608–45,686,341, 14 genes, copy number 5 (within-gene range 3–5): TGM4, AC098649.1, ZDHHC3, RPL12P44, EXOSC7, CLEC3B, RNU5B-3P, CDCP1, RPS24P8, TMEM158, U3, LARS2, LARS2-AS1, LIMD1.
- chr3:91,356,755–96,619,831, 26 genes, copy number 5: ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8.
- chr3:97,481,177–198,222,513, 1,772 genes, copy number 5–10 (broad region; genes not listed).
- chr5:58,198–51,665,048, 731 genes, copy number 5 (broad region; genes not listed).
- chr5:70,968,166–113,488,823, 603 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:141,958,328–143,229,011, 18 genes, copy number 6–7 (within-gene range 4–7): RNF14, AC005740.3, GNPDA1, AC005740.2, NDFIP1, AC091825.3, SPRY4, AC091825.2, AC091825.1, SPRY4-AS1, RPS12P10, FGF1, AC005592.1, LINC01844, AC005592.2, ARHGAP26, ARHGAP26-AS1, AC008533.1.
- chr5:176,447,628–177,300,213, 23 genes, copy number 6 (within-gene range 4–6): FAF2, RNF44, CDHR2, RN7SL684P, Y_RNA, GPRIN1, SNCB, MIR4281, EIF4E1B, TSPAN17, AC113391.1, AC113391.2, LINC01574, UNC5A, HK3, UIMC1, ZNF346, ZNF346-IT1, FGFR4, NSD1, AC146507.3, AC146507.2, PRMT1P1.
- chr7:116,953,238–117,230,176, 3 genes, copy number 8 (within-gene range 4–8): ST7, ST7-OT4, AC106873.8.
- chr7:116,965,846–117,874,139, 23 genes, copy number 8: AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2.
- chr8:27,311,482–28,083,936, 25 genes, copy number 6–10 (within-gene range 4–10): PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC.
- chr9:127,690,098–127,906,022, 20 genes, copy number 5 (within-gene range 2–5): AL162426.1, PTRH1, MIR3911, CFAP157, TTC16, TOR2A, SH2D3C, AL162586.2, CDK9, MIR3960, MIR2861, FPGS, ENG, AL162586.1, Y_RNA, RNA5SP296, AK1, AL157935.2, MIR4672, ST6GALNAC6.
- chr10:112,424,428–114,427,398, 39 genes, copy number 6 (within-gene range 4–6): ZDHHC6, VTI1A, AC022018.1, MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1, AFAP1L2, RN7SL384P, AL133384.2.
- chr10:114,501,997–114,502,347, 1 gene, copy number 6: AL133384.1.
- chr11:113,314,579–113,949,078, 21 genes, copy number 5 (within-gene range 3–5): TTC12, AP002840.2, ANKK1, AP002840.1, DRD2, MIR4301, TMPRSS5, MTRF1LP1, ZW10, RPS29P19, AP003170.5, AP003170.4, CLDN25, ATF4P4, AP003170.2, LRRC37A13P, USP28, AP003170.3, AP003170.1, RNU6-1107P, HTR3B.
- chr12:3,871,579–4,118,132, 4 genes, copy number 6: PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1.
- chr12:130,651,342–130,669,233, 1 gene, copy number 6: AC095350.1.
- chr13:76,013,023–76,135,225, 2 genes, copy number 5: LINC01034, RN7SL571P.
- chr19:21,082,159–21,656,300, 28 genes, copy number 6: ZNF714, RNA5SP469, VN1R81P, ZNF431, RPL7AP10, VN1R82P, AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1, ZNF493, AC010615.4, AC010615.2, LINC00664, ZNF429, BNIP3P26, AC123912.1, AC123912.4, AC123912.2, AC123912.6, AC123912.5, AC123912.3.
- chr20:31,563,166–64,313,132, 866 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
